Somatic mutation profile of tumor specimen TCGA-AP-A0LP-01A (aliquot TCGA-AP-A0LP-01A-12D-A10B-09) from TCGA case TCGA-AP-A0LP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 76.4 years (27,898 days).
Specimen TCGA-AP-A0LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97d38ceb-6cdd-41a2-bceb-377e41573094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LP-10A (Blood Derived Normal), aliquot TCGA-AP-A0LP-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550986fd-7000-483c-a6ff-3b4c01c49e0a

The open-access MAF lists 353 somatic variants for this specimen: 278 protein-altering or splice-affecting, 65 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 65, Frame Shift Del 56, Frame Shift Ins 18, Nonsense Mutation 13, Splice Site 5, Intron 5, RNA 4, Splice Region 2, 3'Flank 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244197.3 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs193302912, CM149686, COSV61712084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 48/134 reads (36%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 85/206 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 96/236 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.1101dup p.F368Vfs*23 | Frame Shift Ins (INS) | VAF 47/146 reads (32%) | catalogued as rs1422720020; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA4 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV100933120, COSV64674102; called by muse, mutect2, varscan2
- ABCC6 | c.513C>G p.Y171* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52744522; called by muse, mutect2, varscan2
- ACSF2 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs768140243, COSV51955879; called by muse, mutect2, varscan2
- ACSL5 | c.1297G>A p.A433T (on ENST00000354273; = p.A489T on NM_016234.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV61131117; called by muse, mutect2, varscan2
- ACTC1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV51759426; called by muse, mutect2, varscan2
- AKAP14 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV57630089; called by muse, mutect2, varscan2
- ALCAM | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.33); catalogued as rs763977701, COSV60249336, COSV60251366; called by muse, mutect2
- ALG12 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | PolyPhen possibly damaging (0.595); catalogued as rs777173365, COSV58206818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.1966_1968del p.K656del | In Frame Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs750469694; called by pindel, varscan2
- ANKRD12 | c.3325C>T p.R1109W | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147049074; called by muse, mutect2, varscan2
- ANKRD28 | c.2066C>A p.A689E | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67518408; called by muse, mutect2, varscan2
- ANO3 | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 51/112 reads (46%) | catalogued as COSV56793577; called by muse, mutect2, varscan2
- AP2B1 | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV52000062; called by muse, mutect2, varscan2
- ARFGEF2 | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV64212753; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMC2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as rs377502169; called by muse, mutect2, varscan2
- ARMC4 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs772636599, COSV59458683, COSV59464830; called by muse, mutect2, varscan2
- ASH2L | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51699944; called by muse, mutect2, varscan2
- ATG4A | c.303G>C p.W101C | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58965873; called by muse, mutect2, varscan2
- ATP2B3 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs199607295, COSV54849388; called by muse, mutect2
- BAAT | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52289417; called by muse, varscan2
- BAP1 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56233555; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BRD3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs775918544, COSV57701452; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 11/11 reads (100%) | catalogued as rs763134487; called by mutect2, varscan2
- C1S | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV61071093; called by muse, mutect2
- C6orf136 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV53314424; called by muse, mutect2, varscan2
- CAND2 | c.3193C>T p.R1065W (on ENST00000456430 / NM_001162499.2; = p.R948W on NM_012298.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs77920251, COSV99928594; called by muse, varscan2
- CCDC25 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV62958854; called by muse, mutect2, varscan2
- CCDC63 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs770515172, COSV57528827; called by muse, mutect2, varscan2
- CDHR5 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs538514960, COSV57641051; called by muse, mutect2, varscan2
- CDKL1 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53579926; called by muse, mutect2, varscan2
- CHD5 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.099); catalogued as COSV52416077; called by muse, mutect2, varscan2
- CHERP | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs776056169, COSV52225033; called by muse, mutect2, varscan2
- CHRM2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as rs140681489; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 130/338 reads (38%) | catalogued as rs761731080; called by mutect2, varscan2
- CLDN12 | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV55307085; called by muse, mutect2, varscan2
- CLIC2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1032630286, COSV58935736; called by muse, mutect2, varscan2
- CNTRL | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs757104732, COSV53047907; called by muse, mutect2, varscan2
- COL7A1 | c.7453C>T p.R2485C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs868422300, COSV60396155; called by muse, mutect2, varscan2
- CREBBP | c.7192G>T p.G2398* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52126049; called by muse, mutect2, varscan2
- CSMD2 | c.8960A>G p.H2987R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs907590216, COSV53918699; called by muse, mutect2, varscan2
- CSTF3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 157/373 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV60611784; called by muse, mutect2, varscan2
- CUL4A | c.904A>G p.I302V (on ENST00000375440 / NM_001008895.4; = p.I202V on NM_003589.3) | Missense Mutation (SNP) | VAF 175/395 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV58373392; called by muse, mutect2, varscan2
- CXCR5 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1042533380, COSV52681889; called by muse, mutect2, varscan2
- DCAF1 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60043337, COSV60044330; called by muse, mutect2, varscan2
- DCDC1 | c.3043A>G p.I1015V (on ENST00000597505 / NM_001367979.1; = p.I122V on NM_020869.3) | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV60307065; called by muse, mutect2, varscan2
- DGKD | c.980A>G p.N327S (on ENST00000264057 / NM_152879.3; = p.N283S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767771309, COSV51052125; called by muse, mutect2, varscan2
- DHX37 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV58135263; called by muse, mutect2
- DMAP1 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60000818; called by muse, mutect2, varscan2
- DMKN | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV60086808; called by muse, mutect2, varscan2
- DMXL1 | c.4123A>G p.T1375A | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs1301705881, COSV60713082; called by muse, mutect2, varscan2
- DMXL2 | c.3232T>C p.Y1078H | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV51847781; called by muse, mutect2, varscan2
- EIF2A | c.818dup p.N273Kfs*6 | Frame Shift Ins (INS) | VAF 144/414 reads (35%) | catalogued as rs750490771; called by mutect2, pindel, varscan2
- EIF5B | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.626); catalogued as rs574008986, COSV56813566; called by muse, mutect2, varscan2
- EXOC3L1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772773128, COSV52045258; called by muse, varscan2
- F8 | c.4085del p.N1362Tfs*2 | Frame Shift Del (DEL) | VAF 120/490 reads (24%) | catalogued as COSV100812178; called by mutect2, pindel, varscan2
- FAM111A | c.952dup p.M318Nfs*11 | Frame Shift Ins (INS) | VAF 38/94 reads (40%) | catalogued as rs747793861; called by mutect2, varscan2
- FANCA | c.3631C>A p.L1211I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs140143192, COSV57068875; called by muse, mutect2, varscan2
- FGD2 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51463953; called by muse, mutect2, varscan2
- FGD3 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs376360399, COSV61600819; called by muse, mutect2
- FILIP1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs150948880, COSV52722362; called by muse, mutect2, varscan2
- FOXA2 | c.1023_1024del p.Q342Afs*19 (on ENST00000377115 / NM_153675.3; = p.Q348Afs*19 on NM_021784.5) | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV65796415; called by mutect2, pindel, varscan2
- FOXK2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58879550; called by muse, mutect2, varscan2
- GALNT5 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV52038187; called by muse, mutect2, varscan2
- GAPDH | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV57521194; called by muse, mutect2, varscan2
- GAREM1 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52510458; called by muse, mutect2, varscan2
- GAST | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.346); catalogued as COSV61475609; called by muse, mutect2, varscan2
- GATB | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as COSV56130830; called by muse, mutect2, varscan2
- GDPD2 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV65533156; called by muse, mutect2, varscan2
- GIGYF2 | c.2828del p.T943Sfs*10 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as COSV65250195; called by mutect2, pindel, varscan2
- GPR151 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57037892; called by muse, mutect2, varscan2
- GPRASP1 | c.1567T>C p.W523R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64355792; called by muse, mutect2
- GRIP2 | c.2431C>T p.R811W (on ENST00000619221; = p.R714W on NM_001080423.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs576543416, COSV56119427; called by muse, mutect2, varscan2
- GRM3 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781677093, COSV64472865; called by muse, mutect2, varscan2
- HLTF | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 207/485 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs140551459, COSV59501138; called by muse, mutect2, varscan2
- HMBOX1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.188); catalogued as rs749707939, COSV55068825; called by muse, mutect2, varscan2
- HOOK1 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 121/272 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV64619179; called by muse, mutect2, varscan2
- HTT | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.212); catalogued as COSV61863190; called by muse, mutect2, varscan2
- HYDIN | c.9907A>G p.I3303V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV66872044; called by muse, mutect2, varscan2
- IFIT1B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs900196647, COSV65663469; called by muse, mutect2
- IGDCC3 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60077981; called by muse, mutect2, varscan2
- IKZF1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1446212014, COSV58783463, COSV58786626; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs762875806; called by mutect2, varscan2
- INPP4A | c.2063G>A p.G688D (on ENST00000074304 / NM_001134224.1; = p.G649D on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50795996; called by muse, mutect2, varscan2
- IRS4 | c.3391A>G p.S1131G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64534123; called by muse, mutect2
- ITGB1 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as COSV56482586; called by muse, mutect2, varscan2
- KCNK7 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as rs749274421, COSV58419959; called by muse, mutect2, varscan2
- KCNN2 | c.715G>A p.A239T (on ENST00000264773; = p.A451T on NM_021614.4) | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.132); catalogued as COSV53289971, COSV53295744; called by muse, mutect2, varscan2
- KCNT1 | c.2356G>A p.V786I (on ENST00000488444; = p.V805I on NM_020822.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs376955682; called by muse, mutect2, varscan2
- KIF24 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs773256630, COSV52659223; called by muse, mutect2, varscan2
- KIR3DL1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 139/319 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs779002817, COSV58491658; called by muse, mutect2, varscan2
- KLHL42 | c.872+2T>G p.X291_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV67145924; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | catalogued as rs764099275; called by mutect2, varscan2
- KRBA2 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV58779141; called by muse, mutect2, varscan2
- LEMD2 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.562); catalogued as COSV53394205; called by muse, mutect2, varscan2
- LIMK2 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.71); catalogued as COSV59182801; called by muse, mutect2, varscan2
- LONRF3 | c.2183G>T p.S728I (on ENST00000371628 / NM_001031855.3; = p.S687I on NM_024778.5) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV59152970; called by muse, mutect2, varscan2
- LSM14B | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 64/149 reads (43%) | catalogued as COSV53381042; called by muse, mutect2, varscan2
- MANBA | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.523); catalogued as COSV56965896; called by muse, mutect2, varscan2
- MAP3K1 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV68124190; called by muse, mutect2, varscan2
- MAP7 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV63420233; called by muse, mutect2, varscan2
- MARS2 | c.457del p.V153Cfs*89 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as rs1559379211; called by mutect2, varscan2
- MBD6 | c.1843T>C p.S615P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV63074844; called by muse, mutect2, varscan2
- MCRS1 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201670331, COSV57791131; called by muse, mutect2, varscan2
- MED13L | c.5920C>T p.R1974* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56121341; called by muse, mutect2, varscan2
- MED23 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.817); catalogued as COSV63433026; called by muse, mutect2
- METTL6 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV67542195; called by muse, mutect2, varscan2
- MKLN1 | c.2060A>G p.K687R | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV61761121; called by muse, mutect2
- MMP20 | c.93del p.R32Gfs*37 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV99497522; called by mutect2, pindel, varscan2
- MOGS | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV51968834, COSV51970932; called by muse, mutect2, varscan2
- MTTP | c.2312A>G p.Y771C | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55506428; called by muse, mutect2, varscan2
- MTUS2 | c.3472A>G p.I1158V (on ENST00000612955 / NM_001366650.1; = p.I137V on NM_015233.6) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as rs1350765894, COSV60158237; called by muse, mutect2, varscan2
- MUC5B | c.12338G>A p.S4113N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV71592486; called by muse, mutect2, varscan2
- MYO16 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV51798088; called by muse, mutect2, varscan2
- NAIF1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs200200680, COSV66091067; called by muse, mutect2, varscan2
- NAV3 | c.5741G>A p.R1914H (on ENST00000397909 / NM_001024383.2; = p.R1892H on NM_014903.6) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs757028730, COSV57080467; called by muse, mutect2, varscan2
- NDC1 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs138233326; called by muse, mutect2, varscan2
- NDUFB7 | c.282C>T p.D94= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53108396; called by muse, mutect2
- NOVA1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.893); catalogued as COSV57478193; called by muse, mutect2, varscan2
- NPFFR2 | c.1048A>G p.R350G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV58150422; called by muse, mutect2, varscan2
- NPY2R | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs374458370; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 76/232 reads (33%) | catalogued as rs776154715; called by mutect2, varscan2
- NUP153 | c.112-1G>A p.X38_splice | Splice Site (SNP) | VAF 48/132 reads (36%) | catalogued as COSV50450492; called by muse, mutect2, varscan2
- OARD1 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1298479111, COSV55107887; called by muse, mutect2, varscan2
- OAS2 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV60802778; called by muse, mutect2, varscan2
- OR10T2 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs761365250, COSV57780410; called by muse, mutect2, varscan2
- OR51B6 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66513246; called by muse, mutect2, varscan2
- PAN3 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56703915; called by muse, mutect2
- PCBP3 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV68407608, COSV68408261; called by muse, mutect2, varscan2
- PCDHA12 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV56508590; called by muse, mutect2
- PCDHA7 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.186); catalogued as COSV65344637; called by muse, mutect2, varscan2
- PCDHA9 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as COSV65323542, COSV65327324; called by muse, mutect2, varscan2
- PCDHGB6 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as COSV53902951; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | catalogued as rs759495724; called by mutect2, varscan2
- PEDS1-UBE2V1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 101/289 reads (35%) | catalogued as rs1454970558, COSV59012700; called by muse, mutect2, varscan2
- PGA3 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100337311; called by muse, mutect2, varscan2
- PHC2 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs746508855, COSV57104577; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 101/273 reads (37%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHTF1 | c.2075del p.K692Sfs*10 | Frame Shift Del (DEL) | VAF 342/1000 reads (34%) | catalogued as rs752176716, COSV63368077; called by mutect2, pindel, varscan2
- PIWIL4 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54409716; called by muse, mutect2, varscan2
- PLEKHA6 | c.982dup p.V328Gfs*5 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs773765509; called by mutect2, pindel, varscan2
- PLK4 | c.2415-1G>A p.X805_splice | Splice Site (SNP) | VAF 5/102 reads (5%) | catalogued as COSV54637746; called by muse, mutect2
- PLVAP | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763208613, COSV53085480; called by muse, mutect2, varscan2
- PPARA | c.507C>T p.N169= | Splice Region (SNP) | VAF 33/90 reads (37%) | catalogued as rs146427416; called by muse, mutect2, varscan2
- PPP1R26 | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63355815; called by muse, mutect2
- PPP1R36 | c.500dup p.N167Kfs*26 | Frame Shift Ins (INS) | VAF 198/478 reads (41%) | catalogued as rs768324631; called by mutect2, varscan2
- PRDM10 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1338852986, COSV58801688; called by muse, mutect2, varscan2
- PRR30 | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53206482; called by muse, mutect2, varscan2
- PRRC2C | c.6856A>G p.S2286G (on ENST00000367742; = p.S2284G on NM_015172.4) | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV58906488; called by muse, mutect2, varscan2
- PSMC1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54320991; called by muse, mutect2, varscan2
- PSMD7 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1433247617, COSV54697800; called by muse, mutect2, varscan2
- PTPN13 | c.3664C>T p.R1222C (on ENST00000411767 / NM_080683.3; = p.R1203C on NM_006264.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs201663555, COSV57408908; called by muse, mutect2, varscan2
- PTPN2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs145657672; called by muse, mutect2, varscan2
- PUS1 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59035636; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as rs755727862; called by mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 82/218 reads (38%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB41 | c.463A>G p.T155A (on ENST00000374473 / NM_001363807.1; = p.T154A on NM_001032726.3) | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52104214; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 231/512 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1561019512, COSV52787705; called by muse, mutect2, varscan2
- RAPGEF2 | c.3497C>A p.S1166* | Nonsense Mutation (SNP) | VAF 65/176 reads (37%) | catalogued as COSV52428856; called by muse, mutect2, varscan2
- RASSF2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1329141746, COSV65082276; called by mutect2, varscan2
- RBMS1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV62353624; called by muse, mutect2
- RERE | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as rs765016528, CM166774, COSV61943201; called by muse, mutect2, varscan2
- RGL2 | c.1902del p.T635Lfs*36 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as COSV101004786; called by mutect2, pindel, varscan2
- RING1 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232970688, COSV63002225, COSV63002625; called by muse, mutect2
- RLF | c.5410T>G p.S1804A | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65652092; called by muse, mutect2, varscan2
- RNASEH2B | c.925del p.I309Lfs*26 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs75254367; ClinVar: benign / likely benign; called by mutect2, varscan2
- RNF144B | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV52570313; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 70/186 reads (38%) | catalogued as rs752898741; called by mutect2, varscan2
- RXFP1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57050929; called by muse, mutect2, varscan2
- S100A8 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780156471, COSV64198065; called by muse, mutect2, varscan2
- SAFB | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52651644; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 89/291 reads (31%) | catalogued as rs765867975; called by mutect2, varscan2
- SGO2 | c.2864A>G p.Q955R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV63415680; called by muse, mutect2
- SGTA | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1454481670, COSV55594182; called by muse, mutect2
- SH2D7 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51948756; called by muse, mutect2, varscan2
- SLC9A9 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | catalogued as rs752770927, CM157838, COSV57229825, COSV57234111; called by muse, mutect2
- SLITRK6 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV68389749; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 36/402 reads (9%) | catalogued as rs1466680694; called by mutect2, pindel
- SNUPN | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 220/538 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368710928; called by muse, mutect2, varscan2
- SPANXN3 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 136/377 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV65140412; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs752907815; called by mutect2, varscan2
- SPEG | c.7979C>T p.T2660I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV56670572; called by muse, mutect2, varscan2
- SPTBN2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.435); catalogued as COSV59453403; called by muse, mutect2, varscan2
- SVEP1 | c.4231C>T p.P1411S | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57038145; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 96/225 reads (43%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYNGR2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56745208; called by muse, mutect2, varscan2
- SYTL2 | c.2131A>G p.T711A (on ENST00000528231 / NM_001162951.2; = p.T687A on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/522 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV60358738; called by muse, mutect2
- TARDBP | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV53570106; called by muse, mutect2, varscan2
- TASOR2 | c.7087C>T p.R2363* | Nonsense Mutation (SNP) | VAF 67/142 reads (47%) | catalogued as rs766722250, COSV60167805; called by muse, mutect2, varscan2
- TBC1D21 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV55995544; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs763438715; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs763321097; called by mutect2, varscan2
- THEM4 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1249159090, COSV64295354; called by muse, mutect2
- TMCC3 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV54154851; called by muse, mutect2, varscan2
- TMEM106C | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56742859; called by muse, mutect2, varscan2
- TMEM31 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV60327768; called by muse, mutect2, varscan2
- TOP1 | c.1707+2T>C p.X569_splice | Splice Site (SNP) | VAF 53/162 reads (33%) | catalogued as COSV63694257; called by muse, mutect2, varscan2
- TPR | c.5444T>C p.V1815A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs768151378, COSV66601954; called by mutect2, varscan2
- TRAIP | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs770885715, COSV100513340, COSV58914760; called by muse, mutect2, varscan2
- TRHDE | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs766599290, COSV53847095; called by muse, mutect2
- TTC3 | c.4462C>T p.R1488* | Nonsense Mutation (SNP) | VAF 107/271 reads (39%) | catalogued as rs746580573, COSV61291120; called by muse, mutect2, varscan2
- TTC5 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752667962, COSV51871104; called by muse, mutect2, varscan2
- TTN | c.46760C>T p.A15587V (on ENST00000591111; = p.A8163V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | PolyPhen probably damaging (0.997); catalogued as rs370644359; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.7021G>A p.D2341N (on ENST00000591111; = p.D2295N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | PolyPhen possibly damaging (0.476); catalogued as rs781736462, COSV60107188; called by muse, mutect2, varscan2
- TUT4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774119598, COSV57114848; called by muse, mutect2, varscan2
- TUT7 | c.2351A>G p.E784G | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52896130; called by muse, mutect2, varscan2
- USP24 | c.5647A>G p.I1883V | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV53769107; called by muse, mutect2, varscan2
- USP43 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.803); catalogued as rs1167496526, COSV53303300; called by muse, mutect2, varscan2
- USP44 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 43/430 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51564526; called by muse, mutect2, varscan2
- VAT1L | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.267); catalogued as rs772342825, COSV56821276; called by muse, mutect2, varscan2
- VAV3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 328/755 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs746621549, COSV58380604; called by muse, mutect2, varscan2
- WASHC3 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53532326; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 17/33 reads (52%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZAN | c.4702C>A p.L1568M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61810074; called by muse, mutect2
- ZBTB3 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1416196542, COSV67361272; called by muse, mutect2, varscan2
- ZBTB6 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV65409974; called by muse, mutect2, varscan2
- ZDHHC4 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 146/342 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145005587; called by muse, mutect2, varscan2
- ZHX1 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52876756; called by muse, mutect2
- ZHX2 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1563603161, COSV58713704; called by muse, mutect2
- ZKSCAN8 | c.1044A>C p.K348N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57638635; called by muse, mutect2, varscan2
- ZMYM6 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 80/189 reads (42%) | catalogued as rs1373039258, COSV64121145; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 114/290 reads (39%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF184 | c.1091G>T p.C364F | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53004463; called by muse, mutect2, varscan2
- ZNF460 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV64415516, COSV64415770; called by muse, mutect2, varscan2
- ZNF462 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV52936636; called by muse, mutect2
- ZNF501 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.674); catalogued as rs747248884, COSV68516353; called by muse, mutect2, varscan2
- ZNF829 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66986508; called by muse, mutect2
- ACACA | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ACSF2 | c.1595_1596dup p.P533Tfs*12 | Frame Shift Ins (INS) | VAF 28/70 reads (40%) | called by mutect2, varscan2
- ANK2 | c.11462del p.G3821Efs*27 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- C8orf37 | c.501dup p.A168Sfs*17 | Frame Shift Ins (INS) | VAF 240/784 reads (31%) | called by mutect2, pindel, varscan2
- CHMP7 | c.367del p.V123Lfs*6 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- DDX20 | c.1421del p.K474Sfs*6 | Frame Shift Del (DEL) | VAF 57/266 reads (21%) | called by mutect2, pindel, varscan2
- EIF2A | c.1674del p.K558Nfs*3 | Frame Shift Del (DEL) | VAF 109/395 reads (28%) | called by mutect2, pindel, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 102/245 reads (42%) | called by mutect2, varscan2
- ERRFI1 | c.404dup p.N135Kfs*13 | Frame Shift Ins (INS) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- F5 | c.5259dup p.G1754Rfs*5 | Frame Shift Ins (INS) | VAF 13/144 reads (9%) | called by mutect2, pindel
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- GBP2 | c.78dup p.A27Sfs*73 | Frame Shift Ins (INS) | VAF 35/92 reads (38%) | called by mutect2, pindel, varscan2
- H4C5 | c.58_70del p.R20Efs*36 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- IFRD2 | c.376del p.D126Mfs*16 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | called by mutect2, pindel, varscan2
- INPP4A | c.537dup p.R180Tfs*21 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- KCTD6 | c.133del p.D45Tfs*28 | Frame Shift Del (DEL) | VAF 44/111 reads (40%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1292del p.P431Qfs*5 | Frame Shift Del (DEL) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- MUC5B | c.10250del p.P3417Qfs*3 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- NHSL2 | c.1720del p.E574Sfs*32 (on ENST00000510661; = p.E940Sfs*32 on NM_001013627.2) | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 128/342 reads (37%) | called by mutect2, varscan2
- PDZD8 | c.3346del p.I1116* | Frame Shift Del (DEL) | VAF 105/328 reads (32%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.1602del p.V535* | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | called by mutect2, varscan2
- PPP2R2D | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- PRKDC | c.10814del p.N3605Tfs*48 | Frame Shift Del (DEL) | VAF 206/531 reads (39%) | called by mutect2, varscan2
- PRRC2C | c.8378del p.P2793Lfs*5 (on ENST00000367742; = p.P2791Lfs*5 on NM_015172.4) | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- PSD3 | c.2240del p.K747Sfs*73 (on ENST00000440756; = p.K746Sfs*73 on NM_015310.4) | Frame Shift Del (DEL) | VAF 89/235 reads (38%) | called by mutect2, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, varscan2
- RBMXL1 | c.293del p.P98Hfs*39 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | called by pindel, varscan2
- REV3L | c.3450del p.F1150Lfs*15 | Frame Shift Del (DEL) | VAF 47/228 reads (21%) | called by mutect2, pindel, varscan2
- SIN3A | c.1401dup p.D468* | Frame Shift Ins (INS) | VAF 206/549 reads (38%) | called by mutect2, pindel, varscan2
- SLC17A1 | c.33dup p.V12Sfs*19 | Frame Shift Ins (INS) | VAF 65/183 reads (36%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.2487del p.F829Lfs*18 (on ENST00000446997 / NM_001354461.2; = p.F799Lfs*18 on NM_022058.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | called by mutect2, pindel, varscan2
- SLC5A11 | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A1 | c.462del p.F155Sfs*36 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- SMAD2 | c.659dup p.P221Afs*8 | Frame Shift Ins (INS) | VAF 147/410 reads (36%) | called by mutect2, pindel, varscan2
- UNC13C | c.4354del p.Y1452Mfs*29 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- USP32 | c.3247dup p.M1083Nfs*38 | Frame Shift Ins (INS) | VAF 39/123 reads (32%) | called by mutect2, varscan2
- USP54 | c.1020dup p.H341Afs*27 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- XKR5 | c.108dup p.W37Vfs*193 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- ZNF234 | c.942del p.K314Nfs*98 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- ZNF667 | c.788_791del p.N263Rfs*52 | Frame Shift Del (DEL) | VAF 55/243 reads (23%) | called by mutect2, pindel, varscan2
- APBA1 | c.1176C>T p.D392= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs375520741, COSV55229240; called by muse, mutect2, varscan2
- ARMCX2 | c.822G>A p.A274= | Silent (SNP) | VAF 52/90 reads (58%) | catalogued as rs782726644, COSV57530284; called by muse, mutect2, varscan2
- CACNB1 | c.1539G>A p.T513= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV59999050; called by muse, mutect2, varscan2
- CCDC9 | c.63C>T p.I21= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs779356635, COSV55721125; called by muse, mutect2, varscan2
- CEP89 | c.1767G>A p.K589= | Silent (SNP) | VAF 222/501 reads (44%) | catalogued as COSV59864782; called by muse, mutect2, varscan2
- CLK3 | c.1824C>T p.R608= (on ENST00000395066 / NM_001130028.1; = p.R460= on NM_003992.4) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV59340565; called by muse, mutect2, varscan2
- CLUH | c.2517C>T p.A839= (on ENST00000435359; = p.A878= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs959875927, COSV70928890; called by muse, mutect2, varscan2
- COL4A3 | c.126C>T p.D42= | Silent (SNP) | VAF 30/241 reads (12%) | catalogued as rs369251968, COSV67419552; called by muse, mutect2, varscan2
- COPB2 | c.2157G>A p.A719= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs543622675, COSV60350314; called by muse, mutect2, varscan2
- CRACDL | c.204C>T p.S68= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as rs371024776; called by muse, mutect2
- CYP7B1 | c.129C>T p.P43= | Silent (SNP) | VAF 93/195 reads (48%) | catalogued as rs1471365409, COSV59589698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHODH | c.1020C>T p.D340= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs199666119; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DHX57 | c.1212G>A p.S404= | Silent (SNP) | VAF 71/182 reads (39%) | catalogued as rs375508613; called by muse, mutect2, varscan2
- DNAH11 | c.10260C>T p.Y3420= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV60959146; called by muse, mutect2, varscan2
- EGF | c.2727C>T p.H909= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV54479763; called by muse, mutect2, varscan2
- FANCB | c.1080G>A p.T360= | Silent (SNP) | VAF 29/286 reads (10%) | catalogued as rs754983238, COSV60760159; called by muse, mutect2, varscan2
- FBXL14 | c.1032G>A p.T344= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs892968262, COSV59336539; called by muse, mutect2, varscan2
- FUBP1 | c.441C>T p.S147= | Silent (SNP) | VAF 84/192 reads (44%) | catalogued as COSV53931986; called by muse, mutect2, varscan2
- GRIK3 | c.1524C>T p.I508= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs747259388, COSV66135630; called by muse, mutect2, varscan2
- HADHB | c.195G>A p.L65= | Silent (SNP) | VAF 95/248 reads (38%) | catalogued as COSV58546471; called by muse, mutect2, varscan2
- HIF1A | c.2382G>A p.Q794= | Silent (SNP) | VAF 24/595 reads (4%) | catalogued as COSV60189511; called by muse, mutect2
- HRC | c.537G>A p.R179= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV53256723; called by muse, mutect2, varscan2
- IGSF9B | c.534G>A p.T178= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs566699166, COSV58068503; called by muse, mutect2, varscan2
- INTS4 | c.2667G>A p.R889= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV59018656; called by muse, mutect2, varscan2
- IQGAP3 | c.2091C>G p.G697= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV63252085; called by muse, mutect2, varscan2
- ISG20L2 | c.264A>G p.S88= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV57460442; called by muse, mutect2, varscan2
- KIF21A | c.3490C>T p.L1164= (on ENST00000361418 / NM_001378440.1; = p.L1151= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as rs1225382517, COSV62772343; called by muse, mutect2, varscan2
- KIRREL2 | c.336C>T p.S112= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52877070; called by muse, mutect2, varscan2
- MAGI1 | c.3585C>T p.R1195= (on ENST00000402939 / NM_001033057.2; = p.R1224= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV58329545; called by muse, mutect2, varscan2
- MAP1S | c.790C>T p.L264= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs748898900, COSV60722935; called by muse, mutect2, varscan2
- MED22 | c.9G>A p.Q3= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs587713507, COSV59298495; called by muse, mutect2, varscan2
- NCKAP5L | c.3312C>T p.A1104= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs780021918, COSV60128423; called by muse, mutect2, varscan2
- NLRP8 | c.847C>T p.L283= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs561042891, COSV52588591; called by muse, mutect2, varscan2
- NMNAT2 | c.156C>T p.H52= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs201834345, COSV54268902; called by muse, mutect2, varscan2
- ORC1 | c.1656G>A p.Q552= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV65364098; called by muse, mutect2, varscan2
- OTUD5 | c.1686G>A p.V562= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV50236029; called by muse, mutect2, varscan2
- P2RY8 | c.429G>A p.A143= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1256856911, COSV67177499; called by muse, mutect2, varscan2
- PATJ | c.4701C>T p.A1567= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs371984333; called by muse, mutect2, varscan2
- PDGFRL | c.744G>A p.A248= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs753397560, COSV52412829; called by muse, mutect2, varscan2
- PI4KB | c.2157C>T p.G719= (on ENST00000368873 / NM_001369623.1; = p.G731= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1280709801, COSV55015565; called by muse, mutect2, varscan2
- PROKR2 | c.1047G>A p.L349= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV54087098; called by muse, mutect2, varscan2
- PTPRT | c.3634C>T p.L1212= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs542883658, COSV61986164, COSV62035742; called by muse, mutect2, varscan2
- PYROXD2 | c.429A>G p.E143= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV65330047; called by muse, mutect2, varscan2
- RABGAP1L | c.510G>A p.L170= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as COSV52299370; called by muse, mutect2, varscan2
- SACS | c.789C>T p.N263= | Silent (SNP) | VAF 107/226 reads (47%) | catalogued as rs771920263, COSV66538577; ClinVar: likely benign; called by muse, mutect2, varscan2
- SBNO1 | c.2193C>T p.D731= (on ENST00000420886; = p.D730= on NM_018183.5) | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs776697879, COSV57342279; called by muse, mutect2, varscan2
- SDK1 | c.1569C>T p.G523= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV67371778; called by muse, mutect2, varscan2
- SHF | c.282G>A p.R94= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV52050741; called by muse, mutect2, varscan2
- SLC5A12 | c.1167C>T p.G389= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as rs140205490, COSV68449386; called by muse, varscan2
- SLCO3A1 | c.684C>T p.C228= | Silent (SNP) | VAF 145/357 reads (41%) | catalogued as rs199972220, COSV59224125; called by muse, mutect2, varscan2
- SMYD4 | c.957C>T p.S319= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as rs1200301499, COSV59711873; called by muse, mutect2
- SNX5 | c.399C>T p.L133= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs1367569798, COSV66698029; called by muse, mutect2, varscan2
- SPON2 | c.642G>A p.T214= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs774339710, COSV52055265; called by muse, mutect2, varscan2
- TIMM50 | c.892C>T p.L298= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV58679626; called by muse, mutect2
- TNRC6A | c.1122G>A p.E374= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV59360725; called by muse, mutect2
- TRMT5 | c.618T>C p.I206= | Silent (SNP) | VAF 117/248 reads (47%) | catalogued as COSV50782892; called by muse, mutect2, varscan2
- TSHZ3 | c.2349C>T p.H783= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs368039667; called by muse, mutect2, varscan2
- TTN | c.91068C>T p.S30356= (on ENST00000591111; = p.S22932= on NM_003319.4) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs375176758; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP24 | c.6168C>T p.V2056= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV53769080; called by muse, mutect2, varscan2
- WNK4 | c.855G>A p.L285= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs965461274, COSV53820911; called by muse, mutect2, varscan2
- ZBTB39 | c.657G>A p.T219= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs372298998; called by muse, mutect2, varscan2
- ZCCHC24 | c.462C>T p.G154= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs938222753, COSV64886437; called by muse, mutect2, varscan2
- ZGRF1 | c.5631C>T p.Y1877= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs141181537; called by muse, mutect2, varscan2
- ZNF341 | c.1890G>A p.A630= (on ENST00000375200 / NM_001282935.1; = p.A623= on NM_032819.4) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs746232471, COSV61008973, COSV61011124; called by muse, mutect2, varscan2
- ZNF644 | c.3750A>G p.T1250= (on ENST00000337393 / NM_201269.3; = p.T28= on NM_016620.3) | Silent (SNP) | VAF 196/553 reads (35%) | catalogued as COSV61348092; called by muse, mutect2, varscan2
- AC074085.2 | n.363C>T | RNA (SNP) | VAF 14/35 reads (40%) | catalogued as rs201537844; called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4587G>A | Intron (SNP) | VAF 70/170 reads (41%) | catalogued as COSV54849441; called by muse, mutect2, varscan2
- BTN2A3P | n.140C>T | RNA (SNP) | VAF 52/134 reads (39%) | catalogued as rs763130190; called by muse, mutect2, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 10/41 reads (24%) | catalogued as rs754124024; called by mutect2, pindel
- H2BP2 | chr1:143876095 C>A | 3'Flank (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- MIR409 | n.44G>A | RNA (SNP) | VAF 11/32 reads (34%) | catalogued as rs749590166; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+14G>A | Intron (SNP) | VAF 26/69 reads (38%) | catalogued as rs781893598, COSV65327336; called by muse, mutect2, varscan2
- RORA | c.196+51295del | Intron (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- UBTFL2 | n.684del | RNA (DEL) | VAF 22/66 reads (33%) | catalogued as rs776016662; called by mutect2, varscan2
- Z82195.2 | n.416-19551C>T | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
